Somatic mutation profile of tumor specimen TCGA-CD-8526-01A (aliquot TCGA-CD-8526-01A-11D-2340-08) from TCGA case TCGA-CD-8526, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.5 years (26,840 days).
Specimen TCGA-CD-8526-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b31a21-260b-41d6-8844-ff87a809bdcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8526-10A (Blood Derived Normal), aliquot TCGA-CD-8526-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a53e8aea-89e2-46b8-9618-c0a9126f50ac

The open-access MAF lists 50 somatic variants for this specimen: 41 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Frame Shift Del 4, Nonsense Mutation 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB9 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs568372310, COSV54891988; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1345611154, COSV55029706, COSV99788370; called by muse, mutect2, varscan2
- CDPF1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV53078805; called by muse, mutect2, varscan2
- CNNM4 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65660992; called by muse, mutect2, varscan2
- CNTNAP3 | c.2417T>A p.F806Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99905702; called by muse, mutect2, varscan2
- CYP2A6 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778072113, COSV56535479; called by muse, mutect2, varscan2
- FAH | c.143A>G p.H48R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as COSV55721649; called by muse, mutect2, varscan2
- FAM135B | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50527090, COSV99356181; called by muse, mutect2, varscan2
- GAPDH | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as rs915103365, COSV99975679; called by muse, mutect2, varscan2
- GPR171 | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV56380320, COSV56385718; called by muse, mutect2
- MED12L | c.5992C>A p.Q1998K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV56380327; called by muse, mutect2, varscan2
- NAALADL1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs772880783, COSV100368085, COSV60523612; called by muse, mutect2, varscan2
- NALCN | c.5185G>A p.D1729N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.069); catalogued as rs1259310102, COSV51938067; called by muse, mutect2, varscan2
- NBPF1 | c.1852C>A p.Q618K | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs761661482, COSV99844969; called by muse, varscan2
- NLGN4X | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.364); catalogued as rs1200279731, COSV52019676; called by muse, mutect2, varscan2
- NOS3 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52490283; called by muse, mutect2, varscan2
- OR10J1 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV101419820, COSV71128907; called by muse, mutect2
- OR10V1 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55696844; called by muse, mutect2
- OR2T12 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58775959, COSV58779902; called by muse, mutect2, varscan2
- PCDHB8 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50760973; called by muse, mutect2, varscan2
- PCGF6 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV61495147; called by muse, mutect2, varscan2
- PHIP | c.4513C>G p.R1505G | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV51503456, COSV51504994; called by muse, mutect2, varscan2
- PKP3 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs754533171, COSV58986491; called by muse, mutect2, varscan2
- PLIN2 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52803340; called by muse, mutect2, varscan2
- PRKAA2 | c.124G>C p.V42L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64803984; called by muse, mutect2, varscan2
- PTPRD | c.2803G>A p.V935I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs375803455, COSV61956683; called by muse, mutect2, varscan2
- PURB | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV67480355; called by muse, mutect2, varscan2
- RXFP3 | c.1375C>A p.R459S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.091); catalogued as rs533555760, COSV57505826, COSV57508112; called by muse, mutect2, varscan2
- SLC25A20 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV100033908; called by muse, mutect2, varscan2
- SYNPO | c.2584C>T p.R862C (on ENST00000394243 / NM_001166208.2; = p.R618C on NM_007286.6) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs199689202; called by muse, mutect2, varscan2
- TRAIP | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58914601; called by muse, mutect2, varscan2
- TTLL5 | c.3451G>T p.A1151S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377099575; called by muse, mutect2, varscan2
- TTN | c.5339C>T p.T1780I (on ENST00000591111; = p.T1734I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/133 reads (14%) | PolyPhen possibly damaging (0.603); catalogued as COSV60089015; called by muse, mutect2, varscan2
- UTRN | c.6297G>C p.W2099C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62336450; called by muse, mutect2, varscan2
- ZNF106 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs769012043, COSV55514929; called by muse, mutect2, varscan2
- ZNF772 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs199665856, COSV58410653; called by muse, mutect2, varscan2
- CARM1 | c.266_267del p.E89Vfs*101 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- JUN | c.930_931del p.K311Sfs*6 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | called by mutect2, pindel, varscan2
- LCT | c.3139_3140del p.D1047Lfs*8 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.268_271del p.L91Rfs*17 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- BICDL1 | c.891C>T p.G297= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV101287524; called by muse, mutect2, varscan2
- DOCK4 | c.5784G>A p.P1928= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs904210669, COSV70237712, COSV70241957; called by muse, mutect2
- FFAR3 | c.684G>A p.A228= | Silent (SNP) | VAF 39/226 reads (17%) | catalogued as rs377408543; called by muse, mutect2, varscan2
- OR2L3 | c.630C>T p.F210= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV63456128; called by muse, mutect2
- REEP2 | c.678G>A p.A226= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs373069993; called by muse, mutect2, varscan2
- RPS18 | c.348G>A p.K116= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV101005590, COSV65851635; called by muse, mutect2, varscan2
- VNN3 | c.793C>T p.L265= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as COSV99258736; called by muse, mutect2
- KIR3DX1 | n.1028A>T | RNA (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- SNORD114-12 | n.22C>T | RNA (SNP) | VAF 17/87 reads (20%) | catalogued as rs775345470; called by muse, mutect2, varscan2
